Somatic mutation profile of tumor specimen TCGA-33-A5GW-01A (aliquot TCGA-33-A5GW-01A-11D-A27K-08) from TCGA case TCGA-33-A5GW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.3 years (24,586 days).
Specimen TCGA-33-A5GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e3dcf88-5272-4657-b7fd-3b437e2c2fd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-A5GW-10A (Blood Derived Normal), aliquot TCGA-33-A5GW-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/532c7543-920d-45dd-8fd9-2775ecf112f9

The open-access MAF lists 206 somatic variants for this specimen: 146 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 53, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 4, Intron 3, 3'UTR 2, RNA 1, Splice Region 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.3296C>G p.S1099* | Nonsense Mutation (SNP) | VAF 31/47 reads (66%) | catalogued as rs397507663, CM020102, COSV101203844, COSV66456417; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CDKN2A | c.151-2A>G p.X51_splice | Splice Site (SNP) | VAF 17/21 reads (81%) | hotspot (GDC flag); catalogued as rs1554654224, CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL9A2 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535212284, COSV101028331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- ABCA4 | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as CM161632, COSV100933005; called by muse, mutect2, varscan2
- ADGRA3 | c.3948A>T p.K1316N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99292840; called by muse, mutect2, varscan2
- ADGRB2 | c.4269C>G p.F1423L | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV99925569; called by muse, mutect2, varscan2
- ADORA2A | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100417790; called by muse, mutect2, varscan2
- AFF2 | c.1917C>A p.S639R | Missense Mutation (SNP) | VAF 100/127 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99661513; called by muse, mutect2, varscan2
- AFP | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV99889626; called by muse, mutect2, varscan2
- ANKK1 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as rs377018695, COSV100392793, COSV58273354; called by muse, mutect2, varscan2
- APOB | c.2891C>A p.S964* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99263177; called by muse, mutect2, varscan2
- ATG5 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.208); catalogued as COSV100576369; called by muse, mutect2, varscan2
- BNC2 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as rs1295881023, COSV101035153; called by muse, mutect2
- BTBD7 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.396); catalogued as COSV100107867; called by muse, mutect2
- C16orf89 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 7/111 reads (6%) | catalogued as COSV100280685; called by muse, mutect2
- CA11 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50032686, COSV50032866, COSV50033016; called by muse, mutect2
- CATSPER2 | c.1555G>A p.V519M (on ENST00000321596 / NM_001282309.3; = p.V521M on NM_172095.4) | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs752331302, COSV100390510; called by muse, mutect2, varscan2
- CCDC39 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99866845; called by muse, mutect2, varscan2
- CDT1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs1364374363, COSV99967035; called by mutect2, varscan2
- CHRNB4 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99929098; called by muse, mutect2, varscan2
- CKMT2 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV54172016; called by muse, mutect2, varscan2
- CNOT6L | c.887A>G p.Q296R (on ENST00000504123 / NM_001286790.2; = p.Q291R on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99361213; called by muse, mutect2, varscan2
- CNTRL | c.2484-1G>T p.X828_splice | Splice Site (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99440890; called by muse, mutect2, varscan2
- COL7A1 | c.8318C>G p.P2773R | Missense Mutation (SNP) | VAF 86/136 reads (63%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV99866070; called by muse, mutect2, varscan2
- CPAMD8 | c.2885G>C p.R962T (on ENST00000651564; = p.R915T on NM_015692.5) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV101488351, COSV101488599; called by muse, mutect2, varscan2
- DIP2A | c.4340G>A p.G1447E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100595038; called by muse, mutect2, varscan2
- DLD | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.019); catalogued as rs1247456203, COSV99226745; called by muse, mutect2, varscan2
- DLGAP4 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59422049, COSV59424745; called by muse, mutect2, varscan2
- DNAH7 | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100413594; called by muse, mutect2, varscan2
- DNAH8 | c.3340C>A p.R1114S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs200947240, COSV100542713, COSV100542936; called by muse, mutect2, varscan2
- DOP1A | c.6407A>G p.D2136G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99380724; called by muse, mutect2
- DOP1B | c.5812C>T p.R1938C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs536538834, COSV101214937; called by muse, mutect2, varscan2
- DYSF | c.1787C>A p.A596E | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50459563; called by muse, mutect2, varscan2
- EEF1A2 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV99418967; called by muse, mutect2, varscan2
- EIF5B | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as rs1311721943, COSV99176749; called by muse, mutect2, varscan2
- ELP3 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99833745; called by muse, mutect2, varscan2
- EOLA1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV100828388; called by mutect2, varscan2
- FAM166A | c.302T>A p.L101Q | Missense Mutation (SNP) | VAF 111/132 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100457611; called by muse, mutect2, varscan2
- FAM71A | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as COSV99674325; called by muse, mutect2, varscan2
- FANCM | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99950306; called by muse, mutect2, varscan2
- FBXO21 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV100401559; called by muse, mutect2, varscan2
- FBXW7 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 57/86 reads (66%) | catalogued as COSV99898810; called by muse, mutect2, varscan2
- FIBCD1 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99446601; called by muse, mutect2
- FOSB | c.570G>C p.L190F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100798678; called by muse, mutect2, varscan2
- GDPD1 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV99404772; called by muse, mutect2, varscan2
- GNRH2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs200702474; called by muse, mutect2, varscan2
- GPR179 | c.6118G>A p.G2040R (on ENST00000621958; = p.G2039R on NM_001004334.4) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as rs139390296; called by muse, mutect2, varscan2
- GPR37 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100390477; called by muse, mutect2, varscan2
- GRM5 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as COSV100549843; called by muse, mutect2, varscan2
- HBB | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092546; called by muse, mutect2
- HDAC7 | c.2051C>A p.S684* (on ENST00000427332; = p.S723* on NM_015401.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/170 reads (24%) | catalogued as COSV50343707, COSV99315402; called by muse, mutect2, varscan2
- HMGB2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.187); catalogued as COSV99632579; called by muse, mutect2, varscan2
- HSCB | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99319635; called by muse, mutect2, varscan2
- IFT80 | c.2011A>T p.N671Y | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100424289; called by muse, mutect2, varscan2
- IFT81 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1248996456, COSV54366537; called by muse, mutect2, varscan2
- JMJD1C | c.6640G>C p.D2214H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100550077; called by muse, mutect2, varscan2
- KIAA0100 | c.1349-2A>T p.X450_splice | Splice Site (SNP) | VAF 45/91 reads (49%) | catalogued as COSV101197200; called by muse, mutect2, varscan2
- KIAA0753 | c.2763C>G p.F921L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100810517; called by muse, mutect2, varscan2
- KLHL5 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV99784680; called by muse, mutect2, varscan2
- KRT25 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100379775; called by muse, mutect2, varscan2
- LILRB1 | c.1799G>A p.R600Q (on ENST00000427581; = p.R550Q on NM_006669.6) | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs773925105, COSV100206809; called by muse, mutect2, varscan2
- MAGEF1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.257); catalogued as COSV58634401; called by muse, varscan2
- MAGT1 | c.218C>T p.S73F (on ENST00000618282 / NM_001367916.1; = p.S105F on NM_032121.5) | Missense Mutation (SNP) | VAF 101/132 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868965086, COSV63780945; called by muse, mutect2, varscan2
- MAP1A | c.5196G>C p.E1732D | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100287968; called by muse, mutect2, varscan2
- MAP9 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV100250668; called by muse, mutect2, varscan2
- MCF2L | c.1119G>C p.K373N (on ENST00000375608; = p.K341N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV100982059; called by muse, mutect2
- MMP16 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1311546563, COSV99685647, COSV99690667; called by muse, mutect2, varscan2
- MTMR3 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765053016, COSV60303742; called by muse, mutect2, varscan2
- MUC7 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100512163; called by muse, mutect2, varscan2
- MYH4 | c.2514C>G p.F838L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV99700215; called by muse, mutect2, varscan2
- MYH8 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1169419511, COSV101238084; called by muse, mutect2, varscan2
- MYLK3 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.368); catalogued as COSV101189039, COSV67363170; called by muse, mutect2, varscan2
- MYO7A | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV101289016; called by muse, mutect2, varscan2
- NCOA3 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100507024; called by muse, mutect2, varscan2
- NDNF | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV101113080; called by muse, mutect2, varscan2
- NLRP5 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101173316, COSV66767529; called by muse, mutect2, varscan2
- NUCB1 | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV54387490, COSV99617646; called by muse, mutect2, varscan2
- NUDT22 | c.256T>G p.S86A | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.676); catalogued as COSV99655597; called by muse, mutect2, varscan2
- OAT | c.200-1G>T p.X67_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV64348380; called by muse, mutect2, varscan2
- OR1C1 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV101376174, COSV68716002; called by muse, mutect2, varscan2
- OR52A5 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100263260; called by muse, mutect2, varscan2
- OR5K2 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV101415944; called by muse, mutect2, varscan2
- OR5W2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100747523, COSV60615636; called by muse, mutect2, varscan2
- OR8J3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100040491; called by muse, mutect2, varscan2
- PGLS | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV99395599; called by muse, mutect2, varscan2
- PIK3AP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as COSV100225433; called by muse, mutect2
- PLD5 | c.1331T>C p.V444A (on ENST00000442594; = p.V382A on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100138522; called by muse, mutect2, varscan2
- PLEKHF1 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV101460747; called by muse, mutect2, varscan2
- PLEKHH2 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.347); catalogued as COSV56751774, COSV99174268; called by muse, mutect2, varscan2
- PLEKHM3 | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV101216202; called by muse, mutect2, varscan2
- PLIN2 | c.777G>C p.L259= | Splice Region (SNP) | VAF 71/200 reads (36%) | catalogued as COSV99438660; called by muse, mutect2, varscan2
- POC1A | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99623863; called by muse, mutect2, varscan2
- POT1 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV62929292; called by muse, mutect2, varscan2
- PPFIA4 | c.1334A>G p.H445R (on ENST00000447715; = p.H441R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99690182; called by muse, mutect2, varscan2
- PSMD11 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99912285; called by muse, mutect2, varscan2
- RNF125 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV99470333; called by muse, mutect2, varscan2
- RNF40 | c.1168A>T p.M390L | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100221860; called by muse, mutect2, varscan2
- RP1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1483084207, COSV99606025; called by muse, mutect2, varscan2
- RSPRY1 | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV101070894; called by muse, mutect2, varscan2
- RUVBL1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV100494016, COSV59474860; called by muse, mutect2
- RXFP3 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV100347200, COSV57504137; called by muse, mutect2, varscan2
- RYR3 | c.13427T>A p.L4476Q (on ENST00000389232; = p.L4477Q on NM_001036.6) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211854; called by muse, mutect2, varscan2
- SATL1 | c.945C>G p.S315R (on ENST00000395409; = p.S502R on NM_001012980.2) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV100260645; called by muse, mutect2, varscan2
- SBNO1 | c.1435G>T p.A479S (on ENST00000420886; = p.A478S on NM_018183.5) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99928611; called by muse, mutect2, varscan2
- SEC16A | c.2212G>T p.V738F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51531047, COSV99255810; called by muse, mutect2, varscan2
- SELP | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738831; called by muse, mutect2, varscan2
- SERPINI1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.961); catalogued as COSV99854785; called by muse, mutect2, varscan2
- SIN3B | c.3415G>C p.E1139Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV56132575, COSV99932057; called by muse, mutect2, varscan2
- SLC13A2 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100120021; called by muse, mutect2, varscan2
- SLC2A3 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99306206; called by muse, mutect2, varscan2
- SLC35A5 | c.1175A>G p.D392G | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.107); catalogued as COSV99656675; called by muse, mutect2
- SLITRK1 | c.1728G>C p.E576D | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100999753, COSV65674839; called by muse, mutect2, varscan2
- SMCR8 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV100328871; called by muse, mutect2
- SNRNP25 | c.141G>C p.K47N (on ENST00000383018; = p.K38N on NM_024571.4) | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs999318180, COSV99244139; called by muse, mutect2, varscan2
- SNW1 | c.497G>C p.R166P | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99834143; called by muse, mutect2, varscan2
- SOGA3 | c.1693G>C p.G565R | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100846739; called by muse, mutect2, varscan2
- SPTBN5 | c.8056G>A p.A2686T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100310497; called by muse, mutect2, varscan2
- SRSF11 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100917782, COSV63936774; called by muse, mutect2, varscan2
- SUZ12 | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100496633; called by muse, mutect2, varscan2
- TACR1 | c.670T>C p.W224R | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460165420, COSV100537633; called by muse, mutect2, varscan2
- TBL1XR1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV61789246, COSV61789805; called by muse, varscan2
- TMEM225 | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100902735; called by muse, mutect2, varscan2
- TRIOBP | c.4947G>C p.Q1649H | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100730529; called by muse, mutect2
- TRIP12 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99389113; called by muse, mutect2
- TRPM7 | c.3941A>G p.H1314R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs775269209, COSV100539305; called by muse, mutect2, varscan2
- TSHZ2 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV61590842; called by muse, mutect2, varscan2
- TTC3 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100694924; called by muse, mutect2, varscan2
- TTLL11 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); catalogued as COSV100388342, COSV58646181; called by muse, mutect2, varscan2
- UBASH3A | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99369133; called by muse, mutect2, varscan2
- UHRF2 | c.1447A>G p.N483D | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as COSV99436043; called by muse, mutect2, varscan2
- UTP20 | c.5374C>A p.H1792N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as COSV99880631; called by muse, mutect2
- ZNF267 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV100339467; called by muse, mutect2, varscan2
- ZNF660 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100502586; called by muse, mutect2, varscan2
- ZNF784 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100323092; called by muse, mutect2
- ZNF813 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV101124665; called by muse, mutect2, varscan2
- ZNHIT2 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV54204280, COSV54205392, COSV54205400; called by muse, mutect2, varscan2
- ZSCAN21 | c.1172A>T p.N391I | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); catalogued as COSV99460558; called by muse, mutect2, varscan2
- BRD7 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- F8 | c.4403_4427del p.T1468Kfs*91 | Frame Shift Del (DEL) | VAF 43/62 reads (69%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL2 | c.522del p.A175Lfs*46 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- SLC27A1 | c.1352_1363del p.V451_N455delinsD | In Frame Del (DEL) | VAF 5/38 reads (13%) | called by pindel, varscan2
- TP53 | c.137_165del p.S46* | Frame Shift Del (DEL) | VAF 99/201 reads (49%) | called by mutect2, pindel
- UBE2L3 | c.346del p.Q116Sfs*10 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ZNF442 | c.206-12_210del p.X69_splice | Splice Site (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- ADAM7 | c.585C>A p.I195= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV99442836, COSV99443656; called by muse, mutect2, varscan2
- ANK2 | c.7956A>G p.L2652= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV99999135; called by muse, mutect2, varscan2
- ARHGAP45 | c.1108C>T p.L370= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100490281; called by muse, mutect2
- ARPP19 | c.338G>A p.*113= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as COSV51119662, COSV99992822; called by muse, mutect2, varscan2
- ATM | c.5454C>A p.G1818= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV99586870; called by muse, mutect2, varscan2
- ATP6V0E2 | c.189G>A p.L63= (on ENST00000425642; = p.L112= on NM_145230.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/67 reads (72%) | catalogued as COSV101374565; called by muse, mutect2, varscan2
- C4A | c.3817C>T p.L1273= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV101418291; called by muse, mutect2, varscan2
- CENPF | c.1527C>G p.L509= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100871446; called by muse, mutect2, varscan2
- COL5A3 | c.3570G>A p.G1190= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV99318099; called by muse, mutect2
- COLGALT2 | c.273T>A p.T91= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100730329; called by muse, mutect2, varscan2
- ENG | c.1590C>T p.F530= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100785194; called by muse, mutect2, varscan2
- ENG | c.1401C>T p.I467= | Silent (SNP) | VAF 54/279 reads (19%) | catalogued as rs774869479, COSV61228278; called by muse, mutect2, varscan2
- EYS | c.1236T>C p.C412= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100675552; called by muse, mutect2, varscan2
- FAM135B | c.3906G>T p.L1302= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV99417798; called by muse, mutect2
- FAM168B | c.417T>G p.P139= | Silent (SNP) | VAF 9/280 reads (3%) | catalogued as COSV101112207; called by muse, mutect2
- FPGS | c.549C>T p.L183= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as COSV100948763; called by muse, mutect2, varscan2
- FPGS | c.1734G>A p.L578= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100785193; called by muse, mutect2, varscan2
- GLB1L2 | c.933C>T p.S311= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs1177027241, COSV100335076; called by muse, mutect2, varscan2
- LAMC3 | c.4392G>C p.L1464= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100735871; called by muse, mutect2, varscan2
- LRTM2 | c.825G>A p.E275= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs768306678, COSV99764946; called by muse, mutect2, varscan2
- MAFF | c.111G>C p.L37= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100633013; called by muse, mutect2, varscan2
- MAGEB16 | c.114C>G p.L38= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV101303266; called by muse, mutect2, varscan2
- MAN2C1 | c.2304G>T p.R768= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as COSV99145179; called by muse, mutect2, varscan2
- MFSD2A | c.1284G>A p.L428= (on ENST00000372809 / NM_001136493.3; = p.L415= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as COSV100861595; called by muse, mutect2, varscan2
- MYLK2 | c.1566C>T p.V522= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV101044625; called by muse, mutect2, varscan2
- OR51B2 | c.750T>C p.Y250= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs371065028; called by muse, mutect2, varscan2
- OR9A4 | c.855C>G p.L285= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV101516327; called by muse, mutect2, varscan2
- PCDH10 | c.423C>T p.F141= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs1228146574, COSV99992775; called by muse, mutect2
- PCDHB16 | c.1761C>G p.T587= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV99500828; called by muse, mutect2
- PCDHGA9 | c.237G>T p.P79= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV99529111; called by muse, mutect2, varscan2
- PEX5 | c.1326T>A p.P442= (on ENST00000420616; = p.P434= on NM_000319.5) | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV99870632; called by muse, mutect2, varscan2
- PGAM2 | c.522G>A p.Q174= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs534311928, COSV99803462; called by muse, mutect2, varscan2
- PLA2G15 | c.525G>T p.L175= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV99547035; called by muse, mutect2, varscan2
- PLEKHB2 | c.516C>T p.Y172= (on ENST00000409279; = p.Y171= on NM_017958.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99301483; called by muse, mutect2, varscan2
- RAI14 | c.2910T>A p.L970= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV99461582; called by muse, mutect2, varscan2
- RANBP2 | c.7689A>C p.V2563= | Silent (SNP) | VAF 156/427 reads (37%) | catalogued as COSV99311124; called by muse, mutect2, varscan2
- RXFP3 | c.576G>T p.R192= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100347202; called by muse, mutect2, varscan2
- SLC13A2 | c.1584C>T p.F528= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as rs782039519, COSV100120022; called by muse, mutect2, varscan2
- SLC15A4 | c.1147C>T p.L383= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV99903357, COSV99903362; called by muse, mutect2, varscan2
- SNX31 | c.903C>T p.I301= | Silent (SNP) | VAF 79/197 reads (40%) | catalogued as COSV100309847, COSV61262334; called by muse, mutect2, varscan2
- SOS2 | c.966T>C p.F322= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1163616524, COSV99365274; called by muse, mutect2, varscan2
- SPAG4 | c.1263C>T p.H421= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs777022994, COSV65331113; called by muse, mutect2, varscan2
- SYBU | c.973T>C p.L325= (on ENST00000276646 / NM_001099754.2; = p.L324= on NM_017786.6) | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as rs565611782, COSV99405611; called by muse, mutect2, varscan2
- SYNM | c.4416C>T p.I1472= (on ENST00000336292 / NM_145728.3; = p.I1160= on NM_015286.6) | Silent (SNP) | VAF 121/303 reads (40%) | catalogued as COSV100018323; called by muse, mutect2, varscan2
- TEP1 | c.1527G>C p.A509= | Silent (SNP) | VAF 37/49 reads (76%) | catalogued as COSV99401495; called by muse, mutect2, varscan2
- TRIM42 | c.642C>T p.L214= | Silent (SNP) | VAF 36/189 reads (19%) | catalogued as COSV53882907, COSV53886632; called by muse, mutect2, varscan2
- TSC2 | c.3897C>A p.V1299= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99552366; called by muse, mutect2, varscan2
- TTC7B | c.1278G>C p.L426= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100127107; called by muse, mutect2, varscan2
- UAP1 | c.18C>G p.L6= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV54850649; called by muse, mutect2
- UBASH3A | c.714C>A p.A238= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99369128; called by muse, mutect2, varscan2
- ZNF208 | c.1740C>A p.P580= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101236697; called by muse, mutect2, varscan2
- ZNF304 | c.1947T>G p.G649= | Silent (SNP) | VAF 73/196 reads (37%) | catalogued as COSV99988341; called by muse, mutect2, varscan2
- ZNF804A | c.3408A>T p.P1136= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV100166042; called by muse, mutect2, varscan2
- DIP2A | c.2394+19A>G | Intron (SNP) | VAF 30/87 reads (34%) | catalogued as rs778540566; called by muse, mutect2, varscan2
- NELFA | c.668-10C>A | Intron (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100372755; called by muse, varscan2
- RN7SL484P | chr15:99792000 T>A | 3'Flank (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+178G>A | Intron (SNP) | VAF 25/61 reads (41%) | catalogued as COSV100560738; called by muse, mutect2, varscan2
- SSPOP | n.3136G>T | RNA (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100022062; called by muse, mutect2, varscan2
- ZNF99 | c.*792_*793delinsA | 3'UTR (DEL) | VAF 11/60 reads (18%) | called by pindel, varscan2*
- ZNF99 | c.*176T>A | 3'UTR (SNP) | VAF 34/81 reads (42%) | catalogued as COSV101233652; called by muse, mutect2, varscan2
